Somatic mutation profile of tumor specimen 0DKRCV from CCDI case PBBYSN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.1 years (1,490 days).
Specimen 0DKRCV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e9e87b8-0688-45a2-9a01-e5f003632484.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKRCH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/50374349-1403-4d3d-8a0e-e0165ea0fba9

The open-access MAF lists 12 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 4, Intron 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCA4 | c.3727C>T p.R1243W | Missense Mutation (SNP) | VAF 245/580 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60786131, COSV60797427; called by muse, mutect2, varscan2
- KRTAP4-11 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 84/273 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs571487800, COSV66948033; called by muse, mutect2, varscan2
- ATP12A | c.328C>A p.Q110K | Missense Mutation (SNP) | VAF 160/489 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- FSD1 | c.412G>T p.V138F | Missense Mutation (SNP) | VAF 247/518 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- RPS15A | c.102C>G p.I34M | Missense Mutation (SNP) | VAF 501/1065 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- CPD | c.3759G>A p.A1253= | Silent (SNP) | VAF 593/1273 reads (47%) | catalogued as rs763221383; called by muse, mutect2, varscan2
- GJA9 | c.72C>A p.I24= | Silent (SNP) | VAF 32/1187 reads (3%) | called by muse, mutect2
- GNPTAB | c.2436C>T p.T812= | Silent (SNP) | VAF 619/1272 reads (49%) | called by muse, mutect2, varscan2
- MUC15 | c.171A>G p.S57= | Silent (SNP) | VAF 72/515 reads (14%) | called by muse, mutect2, varscan2
- IQCA1L | c.*34C>T | 3'UTR (SNP) | VAF 246/827 reads (30%) | catalogued as rs941508092; called by muse, mutect2, varscan2
- LGMN | c.1192-30G>A | Intron (SNP) | VAF 24/356 reads (7%) | catalogued as rs752702173; called by muse, mutect2
- RAPGEF6 | c.3201-92A>G | Intron (SNP) | VAF 62/157 reads (39%) | called by muse, mutect2, varscan2
